Somatic mutation profile of tumor specimen C3N-01200-01 (aliquot CPT0075120012) from CPTAC case C3N-01200, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 56.3 years (20,550 days).
Specimen C3N-01200-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d5433f64-f876-4e0f-9109-6e3ba8458036.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01200-71 (Blood Derived Normal), aliquot CPT0075240001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7b74a807-c558-44aa-81f6-62c6774978b2

The open-access MAF lists 103 somatic variants for this specimen: 58 protein-altering or splice-affecting, 24 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 24, Intron 14, Frame Shift Del 5, 3'UTR 5, Frame Shift Ins 3, In Frame Del 3, Splice Site 2, Nonsense Mutation 2, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAP1 | c.758dup p.T254Dfs*30 | Frame Shift Ins (INS) | VAF 148/388 reads (38%) | catalogued as rs1553645591; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- APOB | c.4114T>A p.S1372T | Missense Mutation (SNP) | VAF 22/230 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as rs140773510; called by muse, mutect2
- ATP1A3 | c.1778C>G p.S593C (on ENST00000545399 / NM_001256214.2; = p.S580C on NM_152296.5) | Missense Mutation (SNP) | VAF 129/360 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57487252; called by muse, mutect2, varscan2
- BTBD3 | c.1207A>C p.K403Q | Missense Mutation (SNP) | VAF 74/270 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); catalogued as rs759996580; called by muse, mutect2, varscan2
- COL18A1 | c.2855C>T p.P952L (on ENST00000359759 / NM_130444.3; = p.P717L on NM_030582.4) | Missense Mutation (SNP) | VAF 32/434 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as rs750422215; called by muse, mutect2
- CZIB | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 87/287 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs562231137; called by muse, mutect2, varscan2
- EEA1 | c.1759C>A p.Q587K | Missense Mutation (SNP) | VAF 72/224 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as rs1172307888; called by muse, mutect2, varscan2
- GLRA3 | c.812C>T p.S271F | Missense Mutation (SNP) | VAF 52/150 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56864626; called by muse, mutect2, varscan2
- ITGB2 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 48/172 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.022); catalogued as rs1053155608, COSV100186060; called by muse, mutect2
- MBP | c.562C>T p.R188W (on ENST00000355994 / NM_001025101.2; = p.R55W on NM_002385.3) | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs766571087; called by muse, mutect2
- MICAL2 | c.1830G>T p.M610I | Missense Mutation (SNP) | VAF 28/284 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV56320093; called by muse, mutect2
- PCDHGA4 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 94/339 reads (28%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.025); catalogued as rs746094461, COSV53925110; called by muse, mutect2, varscan2
- PLCH2 | c.2617G>A p.A873T | Missense Mutation (SNP) | VAF 28/356 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.928); catalogued as rs752883142; called by muse, mutect2
- SLC19A1 | c.646G>T p.D216Y | Missense Mutation (SNP) | VAF 45/170 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as rs776173955, COSV60756989; called by muse, mutect2, varscan2
- CASD1 | c.2264T>C p.I755T | Missense Mutation (SNP) | VAF 74/238 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CASK | c.164G>A p.S55N | Missense Mutation (SNP) | VAF 41/219 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- CLDN8 | c.117C>G p.N39K | Missense Mutation (SNP) | VAF 13/208 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CSMD3 | c.9249T>A p.D3083E (on ENST00000297405 / NM_001363185.1; = p.D2914E on NM_052900.3) | Missense Mutation (SNP) | VAF 72/482 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DCAF7 | c.276_284del p.D93_L95del | In Frame Del (DEL) | VAF 22/186 reads (12%) | called by mutect2, pindel
- DLAT | c.381+2T>C p.X127_splice | Splice Site (SNP) | VAF 92/252 reads (37%) | called by mutect2, varscan2
- DNAH11 | c.11714del p.G3905Vfs*12 | Frame Shift Del (DEL) | VAF 53/192 reads (28%) | called by mutect2, pindel, varscan2
- DNAH5 | c.7391del p.G2464Afs*2 | Frame Shift Del (DEL) | VAF 41/174 reads (24%) | called by mutect2, pindel, varscan2
- ECI2 | c.1175C>G p.S392* (on ENST00000380118 / NM_206836.3; = p.S362* on NM_006117.2) | Nonsense Mutation (SNP) | VAF 8/59 reads (14%) | called by muse, mutect2, varscan2
- ESS2 | c.983T>C p.V328A | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.185); called by muse, mutect2
- FARS2 | c.281A>G p.K94R | Missense Mutation (SNP) | VAF 32/626 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0.027); called by muse, mutect2
- FOXB2 | c.599dup p.Q201Afs*73 | Frame Shift Ins (INS) | VAF 69/201 reads (34%) | called by pindel, varscan2
- GABRA4 | c.494+1G>T p.X165_splice | Splice Site (SNP) | VAF 5/36 reads (14%) | called by muse, varscan2
- GRIPAP1 | c.380_406del p.A127_G135del | In Frame Del (DEL) | VAF 24/136 reads (18%) | called by mutect2, pindel
- IGDCC4 | c.1801A>C p.I601L | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IGHV3-15 | c.82G>T p.G28* | Nonsense Mutation (SNP) | VAF 16/164 reads (10%) | called by muse, mutect2
- IPO7 | c.2728G>A p.E910K | Missense Mutation (SNP) | VAF 15/278 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.282); called by muse, mutect2
- KCNG2 | c.1255C>G p.Q419E | Missense Mutation (SNP) | VAF 41/176 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- KIFAP3 | c.2088G>T p.E696D | Missense Mutation (SNP) | VAF 56/193 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- LCE3A | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 124/475 reads (26%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- MEF2D | c.199C>G p.L67V | Missense Mutation (SNP) | VAF 32/496 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- MIEF2 | c.1097G>C p.G366A | Missense Mutation (SNP) | VAF 35/285 reads (12%) | SIFT tolerated (0.63); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- MSH3 | c.857C>A p.P286H | Missense Mutation (SNP) | VAF 107/375 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MTMR3 | c.2322del p.L775Sfs*24 | Frame Shift Del (DEL) | VAF 34/302 reads (11%) | called by mutect2, pindel, varscan2
- MYH10 | c.1018C>G p.H340D | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NNT | c.930G>C p.E310D | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0.009); called by muse, mutect2
- OR9Q2 | c.871A>T p.S291C | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- PKD1 | c.6186G>T p.Q2062H | Missense Mutation (SNP) | VAF 77/323 reads (24%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- PLA2G3 | c.1091T>G p.F364C | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- POLE | c.1399T>A p.Y467N | Missense Mutation (SNP) | VAF 32/207 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RALGAPA1 | c.5306T>G p.L1769R | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- REM1 | c.394G>T p.V132F | Missense Mutation (SNP) | VAF 57/209 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- SALL3 | c.92G>A p.G31E | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- SCAMP3 | c.848C>A p.A283D | Missense Mutation (SNP) | VAF 48/230 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- SNX5 | c.565A>G p.S189G | Missense Mutation (SNP) | VAF 30/194 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.02); called by muse, mutect2
- SPANXN5 | c.154_156del p.L52del | In Frame Del (DEL) | VAF 14/106 reads (13%) | called by mutect2, pindel, varscan2
- SPART | c.783del p.L262* | Frame Shift Del (DEL) | VAF 41/200 reads (21%) | called by mutect2, pindel, varscan2
- SPATS2 | c.235A>C p.K79Q | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); called by muse, mutect2, varscan2
- VHL | c.610_614del p.E204Hfs*50 | Frame Shift Del (DEL) | VAF 157/413 reads (38%) | called by mutect2, pindel, varscan2
- VPS35 | c.1499_1500dup p.E501Lfs*9 | Frame Shift Ins (INS) | VAF 77/325 reads (24%) | called by mutect2, pindel, varscan2
- WDR6 | c.3121C>T p.P1041S | Missense Mutation (SNP) | VAF 152/297 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- ZNF236 | c.4288C>T p.P1430S | Missense Mutation (SNP) | VAF 46/585 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.152); called by muse, mutect2
- ZNF256 | c.1369C>T p.H457Y | Missense Mutation (SNP) | VAF 51/151 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ZNF470 | c.748C>A p.H250N | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ADCY6 | c.2322C>A p.A774= | Silent (SNP) | VAF 74/188 reads (39%) | catalogued as rs1362941438; called by muse, mutect2, varscan2
- AHNAK | c.6627A>T p.V2209= | Silent (SNP) | VAF 183/469 reads (39%) | called by muse, mutect2, varscan2
- AL162231.1 | c.163C>T p.L55= | Silent (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2, varscan2
- CENPE | c.2013A>G p.L671= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as COSV99477122; called by muse, mutect2, varscan2
- CORT | c.15C>T p.P5= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs375806455; called by muse, mutect2
- F5 | c.1590C>T p.S530= | Silent (SNP) | VAF 12/242 reads (5%) | called by muse, mutect2
- FMN2 | c.1119C>T p.D373= | Silent (SNP) | VAF 6/32 reads (19%) | called by muse, mutect2
- FN1 | c.5517G>A p.E1839= | Silent (SNP) | VAF 14/421 reads (3%) | called by muse, mutect2
- IFIH1 | c.2532G>A p.E844= | Silent (SNP) | VAF 40/216 reads (19%) | called by muse, mutect2, varscan2
- ITPKB | c.978G>A p.P326= | Silent (SNP) | VAF 27/416 reads (6%) | catalogued as rs1159881625, COSV55271119; called by muse, mutect2
- KCNG2 | c.1254G>A p.Q418= | Silent (SNP) | VAF 40/175 reads (23%) | called by muse, mutect2, varscan2
- LATS1 | c.3306T>A p.I1102= | Silent (SNP) | VAF 19/81 reads (23%) | called by muse, mutect2, varscan2
- MANBA | c.1452C>T p.Y484= (on ENST00000642252; = p.Y438= on NM_005908.4) | Silent (SNP) | VAF 43/383 reads (11%) | called by muse, mutect2, varscan2
- MFSD6 | c.1326C>T p.L442= | Silent (SNP) | VAF 134/267 reads (50%) | called by muse, mutect2, varscan2
- MS4A4E | c.126G>A p.R42= | Silent (SNP) | VAF 20/226 reads (9%) | catalogued as rs267603050; called by muse, mutect2
- PAK4 | c.939C>T p.D313= | Silent (SNP) | VAF 138/438 reads (32%) | catalogued as rs369018322; called by muse, mutect2
- PLEKHA4 | c.441G>T p.A147= | Silent (SNP) | VAF 60/325 reads (18%) | catalogued as rs1404611123; called by muse, mutect2, varscan2
- PLXDC2 | c.1395C>A p.L465= | Silent (SNP) | VAF 50/146 reads (34%) | catalogued as COSV65904134; called by muse, mutect2, varscan2
- RFTN1 | c.1422A>G p.A474= | Silent (SNP) | VAF 48/478 reads (10%) | called by muse, mutect2
- TMEM181 | c.1344G>A p.L448= | Silent (SNP) | VAF 25/87 reads (29%) | called by muse, mutect2, varscan2
- TRAFD1 | c.498C>G p.S166= | Silent (SNP) | VAF 27/298 reads (9%) | called by muse, mutect2
- TTN | c.84165A>C p.T28055= (on ENST00000591111; = p.T20631= on NM_003319.4) | Silent (SNP) | VAF 20/181 reads (11%) | called by muse, mutect2, varscan2
- VASP | c.1035G>A p.Q345= | Silent (SNP) | VAF 28/337 reads (8%) | catalogued as rs779507656; called by muse, mutect2
- VEZF1 | c.348C>A p.I116= | Silent (SNP) | VAF 65/199 reads (33%) | called by muse, mutect2, varscan2
- AC106741.1 | c.*39G>T | 3'UTR (SNP) | VAF 36/184 reads (20%) | catalogued as rs1339151046; called by muse, mutect2, varscan2
- CCDC188 | c.733-19T>C | Intron (SNP) | VAF 5/24 reads (21%) | catalogued as rs73150876; called by muse, varscan2
- CD320 | c.*205G>C | 3'UTR (SNP) | VAF 116/283 reads (41%) | called by muse, mutect2, varscan2
- DHRS11 | c.358-1345C>G | Intron (SNP) | VAF 8/226 reads (4%) | called by muse, mutect2
- FAM193B | c.1076+18A>C | Intron (SNP) | VAF 77/337 reads (23%) | called by muse, mutect2, varscan2
- FGFR4 | c.1057+165_1057+166del | Intron (DEL) | VAF 104/511 reads (20%) | called by pindel, varscan2
- FOXP2 | c.*2787_*2788del | 3'UTR (DEL) | VAF 8/27 reads (30%) | called by mutect2, pindel, varscan2
- GAS8 | c.90+1439G>C | Intron (SNP) | VAF 20/128 reads (16%) | catalogued as rs778373318; called by muse, varscan2
- HBD | c.-29+230G>C | Intron (SNP) | VAF 62/237 reads (26%) | called by muse, mutect2, varscan2
- LINC02694 | n.107A>C | RNA (SNP) | VAF 17/118 reads (14%) | called by muse, mutect2, varscan2
- MT1G | c.97+82_97+84del | Intron (DEL) | VAF 67/275 reads (24%) | called by mutect2, pindel, varscan2
- PLA2G6 | c.210-29G>T | Intron (SNP) | VAF 83/277 reads (30%) | called by muse, mutect2, varscan2
- RPL4 | c.-24G>A | 5'UTR (SNP) | VAF 30/159 reads (19%) | catalogued as rs371027636; called by muse, mutect2, varscan2
- RTN4R | c.23-414C>A | Intron (SNP) | VAF 28/84 reads (33%) | called by muse, mutect2, varscan2
- SLC11A2 | c.*1609T>C | 3'UTR (SNP) | VAF 16/106 reads (15%) | called by muse, mutect2, varscan2
- SLC2A1 | c.868-50del | Intron (DEL) | VAF 60/276 reads (22%) | called by mutect2, pindel, varscan2
- TCOF1 | c.1279-23C>G | Intron (SNP) | VAF 26/340 reads (8%) | called by muse, mutect2
- TMEM134 | c.329+28C>T | Intron (SNP) | VAF 38/267 reads (14%) | catalogued as rs201248558; called by muse, mutect2, varscan2
- TMEM258 | c.3+19G>T | Intron (SNP) | VAF 29/348 reads (8%) | called by muse, mutect2
- VAPB | c.*4774A>G | 3'UTR (SNP) | VAF 105/422 reads (25%) | catalogued as COSV55666798; called by muse, mutect2, varscan2
- ZEB1 | c.58+43636G>T | Intron (SNP) | VAF 77/235 reads (33%) | called by muse, mutect2, varscan2
